Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7013, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7013-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, TEMPORAL LOBE, EXCISIONAL BIOPSIES: ANAPLASTIC
ASTROCYTOMA. MIB-1 PROLIFERATION INDEX 12% TO 16%.

SEE MICROSCOPIC AND COMMENT.

Operation/Specimen:UPDATED REPORT-Brain. Left temporal lobe tumor
-FS.

Clinical History and Pre-Op Dx: [REDACTED] man with history of
seizures [REDACTED] months ago. MRI shows slightly enhancing lesion in the
temporal lobe.

GROSS PATHOLOGY: A. Received fresh, three fragments, 1.3 cm across
in aggregate. Semi-firm, grayish-brown. In total #1-3.

INTRAOPERATIVE CONSULTATION:

1. Brain, imprint: Scant atypical naked nuclei.
2. Brain, squash preparations: Glioma, C/W high histological grade

B.

SPECIMEN: Left temporal lobe tumor.

FIXATIVE: None.

GENERAL: Six fragments of brain parenchyma, 1.8 up to 3.5 cm. in
greatest dimension. There are areas of hemorrhagic and
gray soft material.

SECTIONS: X1-X3 - representative of each piece.
[REDACTED] [REDACTED]

MICROSCOPIC: A,B. Portions of a glial neoplastic proliferation. The
neoplastic cells have anaplastic elongated nuclei disposed in a heavy
fibrillary background. There are occasional mitotic figures. There is
capillary-type microvasculature with interanastomosing vessels, and
focally there is microvascular cellular proliferation. There is no
necrosis.

SPECIAL STAINS: Immunoperoxidase methods for GFAP and MIB-1 were
performed on sections from blocks #2 and x3.

The GFAP demonstrates the glial fibrillary background of the
tumor. With the MIB-1 labelling indices of 12% and 16% were
determined
in the more active areas.

[page 2 of 2]
COMMENT: The lesion is a glial neoplasm with heavy glial fibrillogenesis. The tumor cells have nuclear anaplastic features, mitotic figures are occasionally observed, and microvascular cellular proliferation is present focally. Necrosis is absent. The neoplasm is a high histological grade glioma (WHO grade IV/IV), however devoid of necrosis. The interanastomosing pattern of the microvasculature suggests an oligodendroglial component.

ADDENDUM REPORT

B.

Tissue not previously submitted from this specimen is now submitted in total, #x4-x9.

Microscopically, this tissue corresponds to brain diffusely and extensively infiltrated by a neoplastic proliferation similar to that one described above. In here, microvascular calcification and a microvascular network of vessels is more prominent. In a couple of microscopic areas there is tumor necrosis associated with microvascular cellular proliferation.

The presence of microscopic zones of necrosis would justify the designation of this tumor as glioblastoma multiforme. Again, an oligodendroglial component is probable in this tumor.

Source: NCI Genomic Data Commons file 23aa45c3-091a-46f1-b7fc-e2bc8b36978c (TCGA-DU-7013.A39CAD6F-249D-4BC5-8D67-9A3FA7E4DCD6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).